Gene-level copy-number profile of tumor specimen TCGA-24-1558-01A from TCGA case TCGA-24-1558, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.9 years (27,004 days).
Specimen TCGA-24-1558-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.59734a4a-9daf-4a2f-b772-443dc12a9100.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1558-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e9b025d-9c59-4e0d-816e-d67b68ef065b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,781; copy number 2: 15,723; copy number 3: 17,256; copy number 4: 20,777; copy number 5: 2,808; copy number 6: 317; copy number 7: 189; copy number 8: 40; copy number 9: 136; copy number 10: 58; copy number 11: 165; copy number 12: 30; copy number 13: 210; copy number 14: 2; copy number 15: 53; copy number 19: 20; copy number 20: 50; copy number 21: 169; copy number 24: 3; copy number 27: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1558-01): tumor purity 0.91, ploidy 3.26, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 908 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,517,217–112,530,165, 59 genes, copy number 12–15: KCNA10, KCNA2, AL365361.1, KCNA3, Y_RNA, NRBF2P3, OR11I1P, CD53, AL360270.2, AL360270.1, LRIF1, AL360270.3, CCNT2P1, RNA5SP54, DRAM2, CEPT1, AL355816.1, AL355816.2, DENND2D, CHI3L2, CHIAP1, CHIAP2, CHIA, AL356387.1, AL356387.2, PIFO, CHIAP3, HIGD1AP12, PGBP, OVGP1, AL390195.2, UBE2FP3, AL390195.1, WDR77, Y_RNA, ATP5PB, C1orf162, TMIGD3, RNU6-792P, ADORA3, RAP1A, LINC01160, KRT18P57, RNU6-151P, INKA2, INKA2-AS1, AL049557.1, DDX20, KCND3, KCND3-IT1, KCND3-AS1, LINC01750, LINC02884, TXNP3, AL591521.1, CTTNBP2NL, MIR4256, WNT2B, AL354760.1.
- chr10:31,033,089–38,783,108, 141 genes, copy number 9–27 (within-gene range 5–27) (broad region; genes not listed).
- chr11:22,010,402–22,170,001, 2 genes, copy number 14 (within-gene range 4–14): AC116534.1, AC107882.1.
- chr11:29,159,956–29,276,565, 2 genes, copy number 12: AC090791.1, AC110056.1.
- chr11:29,391,525–29,631,515, 4 genes, copy number 12: AC090124.2, AC090124.1, AC110058.1, LINC02546.
- chr16:10,214,784–16,953,468, 193 genes, copy number 9–21 (broad region; genes not listed).
- chr19:9,721,903–10,380,572, 46 genes, copy number 10: AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G, DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2.
- chr19:12,132,117–12,748,323, 50 genes, copy number 20 (within-gene range 5–20): ZNF625-ZNF20, AC022415.1, ZNF625, ZNF136, AC012618.3, ZNF44, AC012618.1, AC012618.2, ZNF563, ZNF442, RPS29P23, AC008758.4, AC008758.3, ZNF799, AC008758.5, ZNF443, AC008758.6, AC008758.2, ZNF709, AC008758.1, MTND2P40, MTCO1P27, MTCO2P27, MTATP6P27, PPIAP20, ZNF564, AC010422.6, AC010422.4, AC010422.1, PGK1P2, ZNF490, ZNF791, RPL10P16, AC010422.3, MAN2B1, AC010422.5, WDR83, AC010422.8, WDR83OS, AC010422.7, DHPS, AC010422.2, GNG14, FBXW9, AC018761.4, TNPO2, SNORD41, AC018761.1, TRIR, GET3.
- chr19:12,965,159–14,778,560, 76 genes, copy number 9–19 (broad region; genes not listed).
- chr19:14,792,318–14,792,533, 1 gene, copy number 9: AC005255.1.
- chr19:17,009,189–17,590,071, 42 genes, copy number 9: AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1.
- chr19:17,613,722–17,623,338, 2 genes, copy number 9: AC008761.2, AC008761.3.
- chr19:29,287,011–30,713,538, 22 genes, copy number 9–10 (within-gene range 5–10): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536.
- chr19:37,613,749–40,380,439, 142 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr19:41,877,279–44,536,613, 126 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,781. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
